Somatic mutation profile of tumor specimen TCGA-F7-A61V-01A (aliquot TCGA-F7-A61V-01A-11D-A28R-08) from TCGA case TCGA-F7-A61V, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 54.4 years (19,857 days).
Specimen TCGA-F7-A61V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e57f503-1116-4b1f-be8f-37ed43a0a6d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A61V-10A (Blood Derived Normal), aliquot TCGA-F7-A61V-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07063f8c-0295-41ec-8aa3-ba15b8a701f8

The open-access MAF lists 113 somatic variants for this specimen: 91 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 21, Nonsense Mutation 6, Frame Shift Ins 3, Frame Shift Del 2, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.2493-1G>C p.X831_splice | Splice Site (SNP) | VAF 13/63 reads (21%) | catalogued as rs786203451, CS1512647, COSV52010278, COSV52010642, COSV99369411; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.516_524del p.V173_R175del | In Frame Del (DEL) | VAF 31/73 reads (42%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCF3 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1036329869, COSV53050626; called by muse, mutect2, varscan2
- ABHD17B | c.293A>G p.H98R | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763889864, COSV100330089; called by muse, mutect2, varscan2
- ABHD17C | c.950G>T p.R317I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99358521; called by muse, mutect2, varscan2
- AHNAK2 | c.13456G>T p.V4486L | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.171); catalogued as COSV100315493; called by muse, mutect2, varscan2
- AHNAK2 | c.5575C>A p.L1859I | Missense Mutation (SNP) | VAF 130/479 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); catalogued as rs771754205, COSV100315878, COSV60916775; called by muse, varscan2
- ATP1A2 | c.3020G>A p.R1007Q | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs754878991, COSV63403028, COSV63404400; called by muse, mutect2, varscan2
- BRIX1 | c.639T>G p.N213K | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV100384470; called by muse, mutect2
- C10orf62 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 36/157 reads (23%) | catalogued as COSV101035223; called by muse, mutect2, varscan2
- CCDC88B | c.3448C>T p.R1150W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs899463915, COSV57268946; called by muse, mutect2, varscan2
- CEP152 | c.2582A>G p.N861S | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as COSV100358549; called by muse, mutect2, varscan2
- CHKB | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs374544105; called by muse, mutect2, varscan2
- CHST4 | c.897G>T p.L299F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV100632817, COSV58297793; called by muse, mutect2, varscan2
- CLMN | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100112115; called by muse, mutect2
- COL1A1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99866495; called by muse, mutect2, varscan2
- COL4A1 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101010976; called by muse, mutect2, varscan2
- DOCK8 | c.3336T>G p.F1112L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101209810; called by muse, mutect2, varscan2
- ECSIT | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV99368863; called by muse, mutect2, varscan2
- EED | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs1306469162, COSV54555051, COSV54557603, COSV54559327; called by muse, mutect2, varscan2
- EGR2 | c.206G>C p.R69T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.614); catalogued as COSV99653997; called by muse, mutect2, varscan2
- ELF4 | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.88); catalogued as COSV57451241, COSV57454554; called by muse, mutect2, varscan2
- EPHA3 | c.2495A>G p.D832G | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100343273; called by muse, mutect2
- EPPK1 | c.4307C>G p.S1436* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as COSV101599745; called by muse, mutect2, varscan2
- EPPK1 | c.4209C>A p.F1403L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101599746; called by muse, mutect2, varscan2
- ETV2 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876806; called by muse, mutect2, varscan2
- FBXL7 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs760845839, COSV61644189; called by muse, mutect2, varscan2
- FBXO8 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.164); catalogued as COSV101183624; called by muse, mutect2, varscan2
- FLG | c.6841C>A p.H2281N | Missense Mutation (SNP) | VAF 15/509 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.699); catalogued as COSV100910625; called by muse, mutect2
- FN3K | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV100333215; called by muse, mutect2, varscan2
- FNDC3A | c.2432G>T p.G811V (on ENST00000492622 / NM_001079673.2; = p.G755V on NM_014923.5) | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV101256624; called by muse, mutect2, varscan2
- GDF15 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.009); catalogued as COSV53251664, COSV53251779, COSV99416032; called by muse, mutect2, varscan2
- GRK7 | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99379557; called by muse, varscan2
- GUCY2F | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV99484566; called by muse, mutect2, varscan2
- HERPUD1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100295859; called by muse, mutect2, varscan2
- HGD | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.174); catalogued as COSV52196216, COSV99380699; called by muse, mutect2, varscan2
- HMCN1 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99624765; called by muse, mutect2, varscan2
- HOXC4 | c.8T>A p.M3K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100323939; called by muse, mutect2, varscan2
- HOXD9 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.424); catalogued as COSV99981743; called by muse, mutect2, varscan2
- KCNK4 | c.977C>A p.A326D | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100107665, COSV60455150; called by muse, mutect2, varscan2
- KCNT2 | c.257C>G p.P86R | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV54082772, COSV99651800; called by muse, mutect2, varscan2
- KIF23 | c.1191C>G p.F397L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV99531921; called by muse, mutect2, varscan2
- KLRF1 | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.06); catalogued as COSV99684304; called by muse, varscan2
- LCOR | c.4276G>A p.D1426N | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99616623; called by muse, mutect2, varscan2
- LILRB1 | c.401G>A p.C134Y (on ENST00000427581; = p.C98Y on NM_006669.6) | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755174365, COSV100206966; called by muse, mutect2, varscan2
- LUZP1 | c.3091T>C p.C1031R | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.112); catalogued as COSV100034524; called by muse, mutect2, varscan2
- MDN1 | c.7546T>G p.L2516V | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.341); catalogued as COSV101020818; called by muse, mutect2, varscan2
- MIA2 | c.1898G>A p.R633K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV99697343; called by muse, mutect2, varscan2
- MMRN1 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as COSV99306551; called by muse, mutect2, varscan2
- MYH15 | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99842382; called by muse, mutect2, varscan2
- MYO7A | c.3932C>T p.S1311F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV101289050; called by muse, varscan2
- MYO7A | c.4035C>A p.F1345L | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV101289051; called by muse, varscan2
- NIPBL | c.8116G>C p.D2706H | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV99239061; called by muse, mutect2, varscan2
- NLRP9 | c.2863G>C p.D955H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs779015854, COSV100242659; called by muse, mutect2, varscan2
- NRIP2 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as COSV100512752, COSV61702253; called by muse, mutect2, varscan2
- OR2H2 | c.608T>G p.F203C | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100589488; called by muse, varscan2
- PACS2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377453480; called by muse, mutect2, varscan2
- PAM | c.2338G>C p.D780H | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV99173094; called by muse, mutect2, varscan2
- PCDH9 | c.3343G>T p.G1115W (on ENST00000377865 / NM_203487.3; = p.G1081W on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.473); catalogued as COSV100118690; called by muse, mutect2, varscan2
- PCDHGA2 | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV99531912, COSV99547431; called by muse, mutect2, varscan2
- PLXNC1 | c.3610G>A p.V1204I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs139894368; called by muse, mutect2, varscan2
- PMS1 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100575480; called by muse, mutect2, varscan2
- PNPLA2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375693983; called by muse, mutect2, varscan2
- PRTFDC1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV100196770; called by muse, mutect2, varscan2
- PTHLH | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99570769; called by muse, varscan2
- RPL3 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 60/238 reads (25%) | catalogued as COSV99335080; called by muse, mutect2, varscan2
- RSPO1 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100740493; called by muse, mutect2, varscan2
- SHTN1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99598542; called by muse, mutect2, varscan2
- SLC38A2 | c.683G>T p.C228F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as COSV99873756; called by muse, mutect2, varscan2
- SPATA6L | c.670G>A p.V224M (on ENST00000461761 / NM_001353484.2; = p.V166M on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99794832; called by muse, mutect2, varscan2
- SRCAP | c.4639C>T p.P1547S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV99349413; called by muse, mutect2, varscan2
- SRP72 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100714241; called by muse, mutect2, varscan2
- STX1A | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99736248; called by muse, mutect2, varscan2
- SYNJ2 | c.3448C>T p.Q1150* | Nonsense Mutation (SNP) | VAF 26/115 reads (23%) | catalogued as COSV100840037; called by muse, mutect2, varscan2
- TAF4 | c.1399A>G p.M467V | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV99433572; called by muse, mutect2, varscan2
- TAS1R2 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs145050419; called by muse, mutect2, varscan2
- TLN1 | c.3089C>T p.A1030V | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as rs764011686, COSV100147362; called by muse, mutect2, varscan2
- TMEM252 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV101051096; called by muse, mutect2, varscan2
- TOR1AIP1 | c.887G>T p.R296I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99621028; called by muse, mutect2, varscan2
- TRMU | c.845A>G p.K282R | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as COSV99324456; called by muse, mutect2, varscan2
- TXNDC15 | c.393C>A p.F131L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100613492; called by muse, varscan2
- TXNDC15 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV100613494; called by muse, varscan2
- UGGT2 | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100948502, COSV100948685; called by muse, mutect2, varscan2
- VIL1 | c.1136C>A p.S379Y | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV99945281; called by muse, mutect2, varscan2
- XIRP2 | c.7666A>C p.S2556R (on ENST00000628543; = p.S2731R on NM_152381.6) | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99739021; called by muse, mutect2
- ZNF835 | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV101606270; called by muse, mutect2, varscan2
- LAMA3 | c.8612del p.N2871Ifs*5 (on ENST00000313654 / NM_198129.4; = p.N1262Ifs*5 on NM_000227.6) | Frame Shift Del (DEL) | VAF 50/165 reads (30%) | called by mutect2, pindel, varscan2
- MFSD6 | c.1943dup p.A649Sfs*18 | Frame Shift Ins (INS) | VAF 45/195 reads (23%) | called by mutect2, pindel, varscan2
- RAB37 | c.558_561del p.I187Pfs*4 (on ENST00000392613 / NM_001006638.3; = p.I180Pfs*4 on NM_175738.5) | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.3689dup p.M1230Ifs*20 | Frame Shift Ins (INS) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- WDR59 | c.1946dup p.Q650Pfs*23 | Frame Shift Ins (INS) | VAF 28/101 reads (28%) | called by mutect2, pindel, varscan2
- ALS2 | c.468G>A p.A156= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs145506395, COSV99968824; ClinVar: likely benign; called by muse, mutect2, varscan2
- AQR | c.3207G>A p.E1069= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99333313; called by muse, mutect2, varscan2
- CAPZB | c.702A>T p.G234= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV99939609; called by muse, mutect2, varscan2
- CD19 | c.351C>A p.G117= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1228979033, COSV100218038; called by muse, mutect2, varscan2
- CDAN1 | c.2751C>A p.I917= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV100661178; called by muse, mutect2, varscan2
- CRB1 | c.1446C>T p.I482= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs150894028; called by muse, mutect2, varscan2
- DNAH7 | c.2520C>A p.L840= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as COSV100414035; called by muse, mutect2, varscan2
- DNAJC7 | c.1206G>A p.R402= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV100347529; called by muse, mutect2, varscan2
- ENC1 | c.1042C>A p.R348= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV100187927, COSV56632234; called by muse, mutect2, varscan2
- FGF11 | c.495T>C p.R165= | Silent (SNP) | VAF 190/322 reads (59%) | catalogued as COSV99548166; called by muse, mutect2, varscan2
- GPR156 | c.1698C>T p.T566= | Silent (SNP) | VAF 48/206 reads (23%) | catalogued as rs140788830; called by muse, mutect2, varscan2
- GSDMD | c.1101C>T p.L367= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1002221821, COSV99369213; called by muse, mutect2, varscan2
- MMP16 | c.1446G>T p.G482= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV54169780, COSV99686255; called by muse, mutect2, varscan2
- NPDC1 | c.939G>A p.A313= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs1215142533, COSV100063719, COSV58664615; called by muse, mutect2, varscan2
- PCDHB12 | c.1287C>A p.P429= | Silent (SNP) | VAF 96/168 reads (57%) | catalogued as COSV53398555, COSV99506817; called by muse, mutect2, varscan2
- POU6F2 | c.1800C>T p.I600= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1481046296, COSV68867922; called by muse, mutect2, varscan2
- PRSS58 | c.522C>A p.I174= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV101616087; called by muse, mutect2, varscan2
- PTHLH | c.90C>T p.L30= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99570763; called by muse, varscan2
- RALGPS2 | c.1017G>A p.R339= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1214263661, COSV61337174; called by muse, mutect2, varscan2
- TLR3 | c.1524G>A p.L508= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as COSV99710839; called by muse, mutect2, varscan2
- USH2A | c.2604T>C p.C868= | Silent (SNP) | VAF 12/230 reads (5%) | catalogued as COSV56347393; called by muse, mutect2
- NRXN3 | c.602-5379T>C | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99816275; called by muse, mutect2, varscan2
